Somatic mutation profile of tumor specimen TCGA-DD-AAE4-01A (aliquot TCGA-DD-AAE4-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 49.3 years (18,009 days).
Specimen TCGA-DD-AAE4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6f270d9-85b4-426f-b03f-b907e23176f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE4-10A (Blood Derived Normal), aliquot TCGA-DD-AAE4-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a059e560-aaa8-458f-9bf6-54f4869fc776

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 42, Silent 23, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.1306C>T p.P436S (on ENST00000373993 / NM_138932.2; = p.P428S on NM_014576.4) | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV50957440, COSV50964844; called by muse, mutect2, varscan2
- AARD | c.436A>T p.S146C | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100991878; called by muse, mutect2
- ABCC6 | c.4007A>C p.H1336P | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228626; called by muse, mutect2, varscan2
- ABCC6 | c.3572T>G p.V1191G | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99228630; called by muse, mutect2, varscan2
- ACP2 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.195); catalogued as rs942193347, COSV99922205; called by muse, mutect2, varscan2
- ACTR5 | c.536C>A p.S179* | Nonsense Mutation (SNP) | VAF 73/181 reads (40%) | catalogued as COSV54762361, COSV99709985; called by muse, mutect2, varscan2
- AKR7A3 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as COSV100853808; called by muse, mutect2, varscan2
- ANAPC2 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV100119024; called by muse, mutect2, varscan2
- ARAP3 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as rs754569933, COSV53349247, COSV99499618; called by muse, mutect2, varscan2
- ARHGAP45 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV100490636; called by muse, mutect2, varscan2
- CD93 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99849163, COSV99849295; called by muse, mutect2, varscan2
- CHML | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100087318; called by muse, mutect2, varscan2
- CPA6 | c.117T>A p.G39= | Splice Region (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99913436; called by muse, mutect2, varscan2
- CYP8B1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60225918; called by muse, mutect2, varscan2
- DAPK2 | c.943T>A p.W315R | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99977328; called by muse, mutect2, varscan2
- DHX30 | c.619T>G p.F207V (on ENST00000445061 / NM_138615.3; = p.F168V on NM_014966.3) | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV100820002; called by muse, mutect2, varscan2
- DMD | c.6334G>T p.D2112Y | Missense Mutation (SNP) | VAF 246/598 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755634705, COSV100819287; called by muse, varscan2
- DYNC2I1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV101337659; called by muse, mutect2, varscan2
- FBXO42 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981729; called by muse, mutect2
- FMN2 | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs771184346, COSV100144675, COSV100146133; called by muse, varscan2
- GJD4 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV100397180; called by muse, mutect2, varscan2
- GPR143 | c.807T>G p.Y269* | Nonsense Mutation (SNP) | VAF 215/568 reads (38%) | catalogued as CM127603, COSV101102208; called by muse, mutect2, varscan2
- HGFAC | c.707G>A p.W236* | Nonsense Mutation (SNP) | VAF 71/199 reads (36%) | catalogued as COSV100122821; called by muse, mutect2, varscan2
- HYDIN | c.7469C>T p.A2490V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs367546874; called by muse, mutect2, varscan2
- KATNB1 | c.1877T>G p.I626S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV101109162; called by muse, mutect2, varscan2
- LPO | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); catalogued as rs1184145526, COSV51856662; called by muse, mutect2, varscan2
- NBEA | c.8599G>T p.A2867S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs747475015, COSV100079258; called by muse, mutect2, varscan2
- NCL | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100502327; called by muse, mutect2, varscan2
- NOTCH3 | c.3010T>G p.C1004G | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99656920; called by muse, mutect2, varscan2
- NYNRIN | c.3791A>G p.D1264G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101230575; called by muse, mutect2, varscan2
- PHTF2 | c.1154G>T p.R385L (on ENST00000248550 / NM_001366089.1; = p.R347L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV99301539; called by muse, mutect2, varscan2
- PRDX3 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV100045348; called by muse, mutect2, varscan2
- PRKCQ | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.996); catalogued as COSV99576769; called by muse, mutect2, varscan2
- PSME4 | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 237/601 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV101122455; called by muse, mutect2, varscan2
- PTPRK | c.2048C>G p.A683G | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV100950871, COSV63908615; called by muse, mutect2, varscan2
- RICTOR | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1205555082, COSV99704799; called by muse, mutect2, varscan2
- SEC23A | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100305343; called by muse, mutect2, varscan2
- SELENOI | c.665T>G p.F222C | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99564382; called by muse, mutect2, varscan2
- SLC10A2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs755730155, COSV99807890; called by muse, mutect2, varscan2
- STAB1 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100401615; called by muse, mutect2, varscan2
- TMEM179B | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99585117; called by muse, varscan2
- TRPM6 | c.5063A>G p.K1688R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100666235, COSV62506528; called by muse, mutect2, varscan2
- TTLL9 | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100206670; called by muse, mutect2, varscan2
- ZC3H12B | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100161676; called by muse, mutect2
- ZFP82 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs749551905, COSV101089030; called by muse, mutect2, varscan2
- ZNF185 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100248343; called by muse, mutect2, varscan2
- ZNF516 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101487263; called by muse, mutect2, varscan2
- AHDC1 | c.421_423del p.S141del | In Frame Del (DEL) | VAF 38/148 reads (26%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.2431_2432del p.R811Gfs*14 | Frame Shift Del (DEL) | VAF 41/156 reads (26%) | called by pindel, varscan2
- CC2D2A | c.952dup p.V318Gfs*30 | Frame Shift Ins (INS) | VAF 51/154 reads (33%) | called by mutect2, pindel, varscan2
- RP1L1 | c.4763_4775del p.L1588Rfs*72 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ABCC6 | c.3573G>T p.V1191= | Silent (SNP) | VAF 123/252 reads (49%) | catalogued as COSV99228629; called by muse, mutect2, varscan2
- ADGRA1 | c.618G>A p.G206= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs762897266, COSV101192686; called by muse, mutect2, varscan2
- AHNAK2 | c.8553C>G p.S2851= | Silent (SNP) | VAF 72/168 reads (43%) | catalogued as COSV100317185; called by muse, varscan2
- ALX1 | c.885T>C p.F295= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV100374373; called by muse, mutect2, varscan2
- ARHGEF4 | c.480C>T p.S160= | Silent (SNP) | VAF 71/112 reads (63%) | catalogued as rs372979735, COSV58124623; called by muse, mutect2, varscan2
- CHRNB2 | c.1398T>C p.F466= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV100872593; called by muse, mutect2, varscan2
- CHST8 | c.1260T>C p.F420= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99381010; called by muse, mutect2
- CNKSR3 | c.1620G>T p.P540= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs182684451, COSV101401342; called by muse, mutect2, varscan2
- CSMD3 | c.6930T>C p.F2310= (on ENST00000297405 / NM_001363185.1; = p.F2206= on NM_052900.3) | Silent (SNP) | VAF 95/244 reads (39%) | catalogued as COSV99832276; called by muse, mutect2, varscan2
- GRIA4 | c.2316T>A p.V772= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV56887727, COSV99230840; called by muse, mutect2, varscan2
- IRF2BP1 | c.537G>T p.L179= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100138858, COSV56195115; called by muse, mutect2, varscan2
- KIAA2013 | c.357G>C p.A119= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100927123; called by muse, mutect2, varscan2
- KIT | c.1017A>T p.A339= | Silent (SNP) | VAF 133/323 reads (41%) | catalogued as rs1253593989, COSV99854015; called by muse, mutect2, varscan2
- MIA2 | c.657T>A p.A219= | Silent (SNP) | VAF 105/249 reads (42%) | catalogued as COSV99696740; called by muse, mutect2, varscan2
- OR10C1 | c.360C>T p.A120= (on ENST00000622521; = p.A118= on NM_013941.3) | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV101010823; called by muse, mutect2, varscan2
- PCDHA8 | c.1794C>T p.D598= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as rs781942867, COSV65325944; called by muse, mutect2, varscan2
- SAMD4B | c.975C>T p.Y325= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV58750900; called by muse, mutect2, varscan2
- SARS2 | c.162A>G p.A54= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99671262; called by muse, mutect2, varscan2
- SLC22A14 | c.996G>A p.E332= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs765139173, COSV99828213; called by muse, mutect2, varscan2
- TSHZ1 | c.2698C>T p.L900= (on ENST00000580243 / NM_001308210.2; = p.L855= on NM_005786.6) | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100433437, COSV100433580; called by muse, mutect2, varscan2
- ZBTB25 | c.492C>T p.D164= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV101170715; called by muse, mutect2, varscan2
- ZC3H12B | c.2004T>A p.T668= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV100161675; called by muse, mutect2
- ZNF140 | c.984G>A p.P328= | Silent (SNP) | VAF 74/147 reads (50%) | catalogued as rs529439392, COSV60579282; called by muse, mutect2, varscan2
